Gene-level copy-number profile of tumor specimen C3L-02542-03 from CPTAC case C3L-02542, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,544 days).
Specimen C3L-02542-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed78915a-42aa-460b-8343-c17de6ee58a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02542-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/18d82fb1-9c71-4d17-8f60-33ca6dacb5e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 5,337; copy number 2: 48,476; copy number 3: 3,982; copy number 4: 174; copy number 5: 1; copy number 7: 62; copy number 10: 9; copy number 17: 123; copy number 25: 23; copy number 28: 27; copy number 43: 22; copy number 48: 15.

Homozygous deletions (total copy number 0; autosomes only): 143 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,453,209–22,455,740, 75 genes (broad region; genes not listed).
- chr10:19,812,372–23,393,467, 63 genes (broad region; genes not listed).
- chr17:18,411,159–18,414,380, 1 gene: LINC02076.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 282 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,252,820–55,092,534, 50 genes, copy number 25–28 (within-gene range 1–28): AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P.
- chr7:23,480,753–25,949,986, 41 genes, copy number 17: AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, U3, TSEN15P3, AC003985.1, AC005100.1, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC010719.1, MIR148A.
- chr7:27,023,737–29,917,066, 82 genes, copy number 17 (within-gene range 3–17) (broad region; genes not listed).
- chr7:47,275,154–47,582,558, 1 gene, copy number 5: TNS3.
- chr7:116,672,196–117,874,139, 37 genes, copy number 43–48: MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2.
- chr7:151,341,699–151,520,120, 9 genes, copy number 10: NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2.
- chr8:49,909,789–54,871,720, 62 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,335. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
